Somatic mutation profile of tumor specimen TCGA-J4-A67N-01A (aliquot TCGA-J4-A67N-01A-11D-A30E-08) from TCGA case TCGA-J4-A67N, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.4 years (22,420 days).
Specimen TCGA-J4-A67N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 059235b6-a988-436b-9d5f-ca3bda330895.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A67N-10A (Blood Derived Normal), aliquot TCGA-J4-A67N-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8229d38a-4edc-419c-9570-0fe81d4f4ea1

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 14, Silent 6, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM1 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.635); catalogued as rs549919699, COSV53299351; called by muse, mutect2, varscan2
- ARHGEF9 | c.1339A>G p.M447V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53634013; called by muse, mutect2, varscan2
- CCT8L2 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as rs553618420, COSV63461614; called by muse, mutect2, varscan2
- EFEMP1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs771296631, COSV62614855; called by muse, mutect2, varscan2
- EIF4G3 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as rs774268372, COSV51673475; called by muse, mutect2
- FHL1 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 125/170 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1238461729, COSV61779561; called by muse, mutect2, varscan2
- GNGT1 | c.4C>A p.P2T | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.538); catalogued as rs746027091, COSV50352322, COSV50353608; called by muse, mutect2, varscan2
- NCAPH | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53634777, COSV53636227; called by muse, mutect2, varscan2
- NOS2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs969669265, COSV58221496; called by muse, mutect2, varscan2
- RBM44 | c.826T>A p.S276T (on ENST00000611254; = p.S910T on NM_001080504.2) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as COSV57627115; called by muse, mutect2, varscan2
- SCNN1B | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs926712911, COSV56301349; called by muse, mutect2, varscan2
- SORT1 | c.1770A>C p.E590D | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56664033; called by muse, mutect2, varscan2
- TEX9 | c.27G>C p.T9= | Splice Region (SNP) | VAF 13/60 reads (22%) | catalogued as COSV61876720; called by muse, mutect2, varscan2
- TMEM171 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV55129313; called by muse, mutect2
- CDO1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- CHST15 | c.1267_1273del p.L423Cfs*26 (on ENST00000346248 / NM_015892.5; = p.L423Cfs*59 on NM_014863.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- MSH5 | c.270_271dup p.V91Efs*21 | Frame Shift Ins (INS) | VAF 29/137 reads (21%) | called by mutect2, pindel, varscan2
- GRIA1 | c.1989G>A p.T663= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs535451229, COSV53588014; called by muse, mutect2, varscan2
- MUC5AC | c.726C>T p.D242= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs540223217, COSV62253224; called by muse, mutect2
- PALM | c.27G>A p.T9= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as rs377213814; called by muse, mutect2, varscan2
- PCDH11X | c.2574C>T p.N858= | Silent (SNP) | VAF 31/48 reads (65%) | catalogued as COSV53440708; called by muse, mutect2, varscan2
- SLC11A1 | c.1452G>T p.V484= | Silent (SNP) | VAF 14/153 reads (9%) | catalogued as COSV51915514; called by muse, mutect2
- TRANK1 | c.7344G>T p.L2448= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV57139735; called by muse, mutect2
